Gene-level copy-number profile of tumor specimen TCGA-DB-5281-01A from TCGA case TCGA-DB-5281, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 61.2 years (22,342 days).
Specimen TCGA-DB-5281-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.59b5c0ce-a0a1-415e-8847-2c85f8d018d3.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DB-5281-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 390 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d01b16e0-4e39-4114-b27b-fd6a94e4df42

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3,623; copy number 1: 13,884; copy number 2: 40,132; copy number 3: 2,588; copy number 4: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DB-5281-01A-01D-1466-01): tumor purity 0.28, ploidy 3.63, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1,234 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,297,264–90,235,370, 46 genes: IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, AC006453.3, LSP1P5, 5S_rRNA, AC006453.1, AC006453.2, AC006453.4, IGKV2D-40, IGKV1D-39, IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7.
- chr3:98,706,236–137,011,085, 668 genes (broad region; genes not listed).
- chr8:144,262,045–145,066,685, 60 genes: BOP1, MIR7112, SCX, HSF1, DGAT1, AC233992.1, MIR6848, SCRT1, SLC52A2, TMEM249, AC233992.2, FBXL6, ADCK5, CPSF1, MIR939, MIR1234, MIR6849, AC233992.3, SLC39A4, VPS28, TONSL, MIR6893, TONSL-AS1, CYHR1, AC084125.1, KIFC2, FOXH1, PPP1R16A, AC084125.2, GPT, MFSD3, RECQL4, AC084125.4, LRRC14, LRRC24, C8orf82, ARHGAP39, AC084125.3, Metazoa_SRP, AF186192.1, AF186192.2, AF186192.3, ZNF251, ZNF34, RN7SL395P, RPL8, MIR6850, ZNF517, ZNF7, COMMD5, AF235103.3, ZNF250, ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr9:14,475–31,506,615, 399 genes (broad region; genes not listed).
- chr16:11,555–682,870, 61 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 13,852. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
